ORGANOID case 62 — Pancreas Cancer Organoid Profiling (ORGANOID-PANCREATIC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/08f63445-b236-4f97-b76a-2e5f4b3c5ff5

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino.

Biospecimens (2 samples)
- Samples S102, S181 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Normal; Specimen type: 3D Organoid.
